Gene-level copy-number profile of tumor specimen C3N-04278-01 from CPTAC case C3N-04278, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 71.9 years (26,252 days).
Specimen C3N-04278-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 25647a8c-25d5-4f91-8721-19a8cb005d38.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04278-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/f0530669-b01d-4207-aacf-86a115a584cf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 1,799; copy number 2: 20,887; copy number 3: 20,376; copy number 4: 11,300; copy number 5: 2,575; copy number 6: 518; copy number 7: 274; copy number 8: 488; copy number 9: 84; copy number 10: 18; copy number 11: 30; copy number 12: 4; copy number 15: 1; copy number 17: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes (within-gene range 0–3): Y_RNA, RNU6-904P, RPS16P3.
- chr14:18,333,726–18,412,264, 2 genes: CR383658.1, CR383658.2.
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–2): RNU6-457P.
- chr22:18,400,407–18,404,206, 1 gene: PPP1R26P3.
- chr22:18,486,999–18,491,247, 1 gene (within-gene range 0–4): AC023490.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 898 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 9 (within-gene range 5–9): AL627309.1.
- chr1:131,025–157,887, 5 genes, copy number 9: CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr3:167,888,414–198,123,232, 589 genes, copy number 7–9 (broad region; genes not listed).
- chr5:13,250,235–15,939,795, 28 genes, copy number 7–15 (within-gene range 4–15): RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1.
- chr5:40,240,167–43,192,021, 49 genes, copy number 9–10: LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3.
- chr11:49,558,546–50,422,316, 30 genes, copy number 11–12: AC136759.1, AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr15:96,842,069–101,979,093, 125 genes, copy number 7 (broad region; genes not listed).
- chr16:32,869,985–32,888,874, 3 genes, copy number 8–11: BCAP31P2, SLC6A10P, AC142086.1.
- chr16:33,094,204–33,134,499, 3 genes, copy number 12 (within-gene range 5–12): HERC2P8, AC145350.4, AC145350.1.
- chr19:30,850,975–33,521,791, 60 genes, copy number 7: AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD.
- chr22:18,501,794–18,524,935, 3 genes, copy number 10: FAM247B, GGTLC3, Metazoa_SRP.
- chr22:18,615,581–18,625,289, 2 genes, copy number 17: Metazoa_SRP, SUSD2P2.

Autosomal genes at a single copy (total copy number 1): 1,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
